Somatic mutation profile of tumor specimen MP2PRT-PARWTH-TMP1-A (aliquot MP2PRT-PARWTH-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARWTH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,496 days).
Specimen MP2PRT-PARWTH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba50c0fb-5197-41cc-85eb-dd4ea9b08a6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWTH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWTH-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/614ad1d5-1990-486d-bc25-67825ffcce50

The open-access MAF lists 120 somatic variants for this specimen: 79 protein-altering or splice-affecting, 37 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 37, Nonsense Mutation 4, Intron 3, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/280 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 84/322 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2080C>T p.Q694* (on ENST00000614293; = p.Q664* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 45/301 reads (15%) | catalogued as COSV55797684; called by muse, mutect2, varscan2
- ADAMTS15 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748841671, COSV54508883; called by muse, mutect2, varscan2
- ADAMTS2 | c.3028G>A p.G1010S | Missense Mutation (SNP) | VAF 25/533 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs368690576; called by muse, mutect2
- AMHR2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV57687316; called by muse, mutect2, varscan2
- B3GAT1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 69/567 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs150624857; called by muse, mutect2, varscan2
- BRCA2 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 86/266 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV66451898; called by muse, mutect2, varscan2
- CADPS | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 75/477 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV51873529; called by muse, mutect2, varscan2
- CNDP1 | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 29/318 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62595853; called by muse, mutect2, varscan2
- CRPPA | c.1123C>T p.H375Y (on ENST00000407010 / NM_001368197.1; = p.H325Y on NM_001101417.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV67909490; called by muse, mutect2, varscan2
- CSMD3 | c.8543G>A p.R2848Q (on ENST00000297405 / NM_001363185.1; = p.R2679Q on NM_052900.3) | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201914089, COSV52185659, COSV52305294; called by muse, mutect2, varscan2
- DLGAP2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 159/315 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs773233596; called by muse, mutect2, varscan2
- DNAH9 | c.7318G>A p.E2440K | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs764734290, COSV52356485; called by muse, mutect2, varscan2
- EPN2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1567853577; called by muse, mutect2, varscan2
- FILIP1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 116/560 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779152073; called by muse, mutect2, varscan2
- FLG | c.3841G>A p.D1281N | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs763266331; called by muse, mutect2, varscan2
- IGF2BP1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 158/326 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV51734043; called by muse, mutect2, varscan2
- KLF15 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 61/423 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1160068070, COSV56181096; called by muse, mutect2, varscan2
- MBD5 | c.2084C>T p.S695L | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV68697125; called by muse, mutect2
- MOCOS | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 72/675 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV54347033; called by muse, mutect2, varscan2
- OR4S2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56746238; called by muse, mutect2, varscan2
- OR5R1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs778534315, COSV56573663; called by muse, mutect2, varscan2
- PGLYRP2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 56/443 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866891261, COSV52995651; called by muse, mutect2, varscan2
- PLEKHN1 | c.805G>A p.E269K (on ENST00000379409; = p.E217K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/425 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs970356587; called by muse, mutect2, varscan2
- POLA2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777086387; called by muse, mutect2, varscan2
- PTPRK | c.2767G>A p.D923N (on ENST00000368215 / NM_001291984.2; = p.D924N on NM_002844.4) | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs902630929, COSV63893699; called by muse, mutect2, varscan2
- RBBP8NL | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 74/463 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53350779; called by muse, mutect2, varscan2
- RHOBTB1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs149990776; called by muse, mutect2, varscan2
- ROR1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64291339; called by muse, mutect2, varscan2
- SCN2A | c.3585G>A p.W1195* | Nonsense Mutation (SNP) | VAF 80/351 reads (23%) | catalogued as rs1553590224, COSV51855063; called by muse, mutect2, varscan2
- SLIT2 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773585950, COSV56576213; called by muse, varscan2
- SPATA31D1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 36/810 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs753572962; called by muse, mutect2
- SPTBN2 | c.4090C>T p.R1364C | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs372626707; called by muse, mutect2, varscan2
- SRMS | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV99421372; called by muse, mutect2, varscan2
- TDRD5 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV99676342; called by muse, mutect2, varscan2
- TTC6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.399); catalogued as rs1169313866; called by muse, mutect2, varscan2
- WDR87 | c.6529G>A p.D2177N | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.236); catalogued as rs1005429821; called by muse, mutect2, varscan2
- ZBBX | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56782473; called by muse, mutect2, varscan2
- ACTN2 | c.2286C>A p.F762L | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- AL590132.1 | c.1323T>A p.D441E | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- ASPG | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 38/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ATP1B4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 82/1038 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- COL24A1 | c.2692G>A p.V898I | Missense Mutation (SNP) | VAF 34/269 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL28A1 | c.2713G>A p.G905R | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF12L2 | c.691A>T p.I231F | Missense Mutation (SNP) | VAF 24/983 reads (2%) | SIFT tolerated (0.25); PolyPhen benign (0.1); called by muse, mutect2
- DGKI | c.1500G>A p.W500* | Nonsense Mutation (SNP) | VAF 34/328 reads (10%) | called by muse, mutect2, varscan2
- EIF4G3 | c.1903A>T p.M635L | Missense Mutation (SNP) | VAF 26/469 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2
- ENPP3 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.02); called by muse, mutect2
- FBN1 | c.7467T>G p.C2489W | Missense Mutation (SNP) | VAF 19/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRY | c.3631G>A p.E1211K | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOOK3 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTATSF1 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- KCNJ4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 140/457 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- KIAA1217 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- KRT72 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 55/393 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LRRC37A3 | c.4456C>T p.P1486S | Missense Mutation (SNP) | VAF 149/616 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LYZL1 | c.507G>A p.M169I (on ENST00000375500; = p.M123I on NM_032517.6) | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.77); called by muse, mutect2
- MACF1 | c.9140A>T p.E3047V | Missense Mutation (SNP) | VAF 26/197 reads (13%) | called by muse, mutect2, varscan2
- MED13 | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- METTL24 | c.1094G>A p.W365* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- MFAP3L | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2
- MYEF2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NPY2R | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PAX5 | c.608_609insC p.Q204Sfs*39 | Frame Shift Ins (INS) | VAF 95/323 reads (29%) | called by mutect2, pindel, varscan2
- RFX4 | c.1474G>A p.E492K (on ENST00000392842 / NM_213594.3; = p.E398K on NM_032491.6) | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RNF17 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- RYR1 | c.5248G>A p.G1750R | Missense Mutation (SNP) | VAF 129/458 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- RYR1 | c.5249G>A p.G1750E | Missense Mutation (SNP) | VAF 128/459 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SH3RF2 | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SI | c.2375G>C p.R792T | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STPG1 | c.979G>A p.D327N (on ENST00000337248 / NM_001199013.2; = p.D280N on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/394 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SUSD6 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 32/601 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SYNJ2 | c.4342C>T p.P1448S | Missense Mutation (SNP) | VAF 42/620 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2
- TBKBP1 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 34/760 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2
- UBR4 | c.10256C>T p.S3419F | Missense Mutation (SNP) | VAF 29/493 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- USP10 | c.1301T>C p.V434A | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- USP42 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC14 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ADAM22 | c.1752G>A p.G584= | Silent (SNP) | VAF 40/268 reads (15%) | called by muse, mutect2, varscan2
- AJUBA | c.1458C>T p.D486= | Silent (SNP) | VAF 96/490 reads (20%) | catalogued as rs759060977; called by muse, mutect2, varscan2
- ANKRD31 | c.867A>G p.L289= | Silent (SNP) | VAF 83/424 reads (20%) | called by muse, mutect2, varscan2
- ANO8 | c.894C>T p.F298= | Silent (SNP) | VAF 148/433 reads (34%) | called by muse, mutect2, varscan2
- ARL16 | c.24C>T p.A8= | Silent (SNP) | VAF 184/682 reads (27%) | catalogued as rs998544874; called by muse, mutect2
- BPIFA3 | c.189G>A p.G63= | Silent (SNP) | VAF 97/355 reads (27%) | catalogued as rs767997234; called by muse, mutect2, varscan2
- CEP41 | c.1074C>T p.N358= | Silent (SNP) | VAF 123/403 reads (31%) | catalogued as rs763559947; called by muse, mutect2, varscan2
- CSMD2 | c.573C>T p.F191= | Silent (SNP) | VAF 43/274 reads (16%) | catalogued as rs776260217, COSV53904846; called by muse, mutect2, varscan2
- CTNNA3 | c.2421G>A p.L807= | Silent (SNP) | VAF 10/262 reads (4%) | catalogued as COSV65521770; called by muse, mutect2
- DNAI3 | c.2604G>A p.L868= | Silent (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- DRD1 | c.132C>T p.V44= | Silent (SNP) | VAF 139/403 reads (34%) | catalogued as rs1324017480, COSV101192482, COSV67104185, COSV67104552; called by muse, mutect2, varscan2
- DUSP8 | c.768C>T p.I256= | Silent (SNP) | VAF 28/558 reads (5%) | catalogued as rs767343651, COSV59031071; called by muse, mutect2
- ELOA2 | c.183C>T p.H61= | Silent (SNP) | VAF 127/722 reads (18%) | catalogued as rs900691638, COSV55304737; called by muse, mutect2, varscan2
- FAM180A | c.483C>T p.H161= | Silent (SNP) | VAF 78/318 reads (25%) | catalogued as rs573967025, COSV58528024; called by muse, varscan2
- FAM214B | c.1443C>T p.L481= | Silent (SNP) | VAF 82/332 reads (25%) | called by muse, mutect2, varscan2
- FZD3 | c.1113G>A p.L371= | Silent (SNP) | VAF 56/260 reads (22%) | called by muse, mutect2, varscan2
- GFRA4 | c.255C>T p.F85= | Silent (SNP) | VAF 64/606 reads (11%) | called by muse, mutect2, varscan2
- GPRASP2 | c.186C>G p.P62= | Silent (SNP) | VAF 198/715 reads (28%) | called by muse, mutect2, varscan2
- KCNMB1 | c.411C>T p.S137= | Silent (SNP) | VAF 122/464 reads (26%) | catalogued as rs779701228; called by muse, mutect2, varscan2
- MAP2 | c.3999A>T p.V1333= | Silent (SNP) | VAF 42/386 reads (11%) | called by muse, mutect2, varscan2
- MC3R | c.406C>T p.L136= | Silent (SNP) | VAF 70/463 reads (15%) | called by muse, mutect2, varscan2
- NRAP | c.1668G>A p.G556= (on ENST00000359988 / NM_001322945.2; = p.G521= on NM_006175.4) | Silent (SNP) | VAF 75/318 reads (24%) | catalogued as rs779154398; called by muse, mutect2, varscan2
- NXPH3 | c.267C>T p.S89= | Silent (SNP) | VAF 64/606 reads (11%) | called by muse, mutect2, varscan2
- PCSK5 | c.4644G>A p.E1548= | Silent (SNP) | VAF 36/306 reads (12%) | called by muse, mutect2, varscan2
- PLXNB2 | c.2607C>T p.F869= | Silent (SNP) | VAF 55/469 reads (12%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.954C>T p.I318= | Silent (SNP) | VAF 83/297 reads (28%) | called by muse, mutect2, varscan2
- RELN | c.1395C>T p.S465= | Silent (SNP) | VAF 36/314 reads (11%) | called by muse, mutect2, varscan2
- SCUBE1 | c.1983C>A p.L661= | Silent (SNP) | VAF 108/370 reads (29%) | catalogued as rs1168837973; called by muse, mutect2, varscan2
- SRL | c.756C>T p.I252= | Silent (SNP) | VAF 62/342 reads (18%) | called by muse, mutect2, varscan2
- SRRM4 | c.402G>A p.K134= | Silent (SNP) | VAF 34/268 reads (13%) | catalogued as COSV57418231; called by muse, mutect2, varscan2
- TNS1 | c.3735C>T p.S1245= | Silent (SNP) | VAF 160/606 reads (26%) | called by muse, mutect2, varscan2
- TRABD2B | c.528G>A p.R176= | Silent (SNP) | VAF 57/414 reads (14%) | catalogued as rs1404416493; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1254C>T p.L418= | Silent (SNP) | VAF 58/581 reads (10%) | catalogued as rs766801815, COSV64955314; called by muse, mutect2
- TTR | c.366C>T p.P122= | Silent (SNP) | VAF 25/572 reads (4%) | catalogued as COSV99379524; called by muse, mutect2
- UNC13C | c.3399G>T p.V1133= | Silent (SNP) | VAF 40/572 reads (7%) | catalogued as COSV99515254; called by muse, mutect2
- USP42 | c.831T>C p.F277= | Silent (SNP) | VAF 31/314 reads (10%) | called by muse, mutect2, varscan2
- ZNF416 | c.315C>T p.S105= | Silent (SNP) | VAF 16/411 reads (4%) | catalogued as COSV52184095; called by muse, mutect2
- MYC | c.-358G>A | 5'UTR (SNP) | VAF 156/770 reads (20%) | called by muse, mutect2, varscan2
- NEB | c.8890-3054C>T | Intron (SNP) | VAF 65/590 reads (11%) | catalogued as rs374734631; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA3D | c.861+4967G>A | Intron (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- TRPM1 | c.213+33G>A | Intron (SNP) | VAF 75/1236 reads (6%) | catalogued as COSV56630460; called by muse, mutect2
